Somatic mutation profile of tumor specimen TCGA-EY-A2OQ-01A (aliquot TCGA-EY-A2OQ-01A-11D-A19Y-09) from TCGA case TCGA-EY-A2OQ, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 61.1 years (22,309 days).
Specimen TCGA-EY-A2OQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3de9235f-25a1-45c1-b12c-563c34ef1c6f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EY-A2OQ-10A (Blood Derived Normal), aliquot TCGA-EY-A2OQ-10A-01D-A19Y-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cd605f95-95d0-4ec2-8619-e3cbbc7c40d8

The open-access MAF lists 58 somatic variants for this specimen: 45 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 12, Nonsense Mutation 3, Splice Region 1, In Frame Del 1, Splice Site 1, Frame Shift Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.783-8_783-2del p.X261_splice | Splice Site (DEL) | VAF 12/18 reads (67%) | hotspot (GDC flag); called by mutect2, varscan2
- ALAS1 | c.1597C>T p.R533W | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs963162082, COSV59630094; called by muse, mutect2, varscan2
- ARHGAP36 | c.140C>T p.T47M | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs1288631219, COSV99357401; called by muse, mutect2, varscan2
- ARHGEF18 | c.3103A>T p.M1035L (on ENST00000359920 / NM_001130955.2; = p.M931L on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as COSV100149199; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.438); catalogued as rs760084844, COSV100771843; called by muse, mutect2, varscan2
- ARRDC1 | c.1234T>C p.Y412H | Missense Mutation (SNP) | VAF 22/28 reads (79%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV100603586; called by muse, mutect2, varscan2
- C7 | c.1373G>A p.R458Q | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs369303619; called by muse, mutect2, varscan2
- CDH7 | c.791G>A p.R264Q | Missense Mutation (SNP) | VAF 24/31 reads (77%) | SIFT tolerated (1); PolyPhen benign (0.357); catalogued as rs767686297, COSV59883221; called by muse, mutect2, varscan2
- CENPB | c.1168G>T p.G390W | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV100713346; called by muse, mutect2
- CHD4 | c.2336G>A p.R779Q (on ENST00000357008 / NM_001363606.2; = p.R792Q on NM_001273.5) | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58897494; called by muse, mutect2, varscan2
- CRY2 | c.716G>A p.R239H | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as COSV69888739; called by muse, mutect2, varscan2
- ESYT2 | c.1152G>A p.K384= (on ENST00000613624; = p.K308= on NM_020728.3) | Splice Region (SNP) | VAF 34/68 reads (50%) | catalogued as COSV99276366; called by muse, mutect2, varscan2
- GGT5 | c.1247A>G p.Y416C | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99571354; called by muse, mutect2, varscan2
- GRIN3B | c.2672C>T p.S891L | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.28); PolyPhen benign (0.028); catalogued as rs776228228, COSV99312180, COSV99312289; called by muse, mutect2, varscan2
- GULP1 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV100770349; called by muse, varscan2
- IL13RA1 | c.303G>T p.Q101H | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100861700; called by muse, mutect2, varscan2
- ITGA8 | c.1762C>T p.R588* | Nonsense Mutation (SNP) | VAF 6/23 reads (26%) | catalogued as rs1358323528, COSV65237036; called by muse, mutect2, varscan2
- ITSN2 | c.1099C>T p.R367W | Missense Mutation (SNP) | VAF 13/129 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.342); catalogued as rs779962692, COSV100742951; called by muse, mutect2
- LPIN3 | c.368G>T p.G123V | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.546); catalogued as COSV100952938; called by muse, mutect2, varscan2
- LPP | c.1231G>A p.E411K | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as rs147109696; called by muse, mutect2, varscan2
- MCOLN1 | c.1344del p.Y450Ifs*3 | Frame Shift Del (DEL) | VAF 25/71 reads (35%) | catalogued as COSV99654609; called by mutect2, pindel, varscan2
- NALCN | c.2005C>T p.R669C | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.793); catalogued as rs754995809, COSV51923705; called by muse, mutect2, varscan2
- NEB | c.14394G>A p.M4798I | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.041); catalogued as rs1393817126, COSV51466469; called by muse, mutect2, varscan2
- NUP214 | c.4147C>T p.H1383Y | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.191); catalogued as COSV100845188; called by muse, mutect2, varscan2
- OAS3 | c.2810C>T p.S937F | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); catalogued as COSV99966138; called by muse, mutect2, varscan2
- PCDHB3 | c.1582G>A p.E528K | Missense Mutation (SNP) | VAF 116/222 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.127); catalogued as COSV50599244; called by muse, varscan2
- PCDHB7 | c.2164C>T p.R722C | Missense Mutation (SNP) | VAF 26/328 reads (8%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.556); catalogued as rs1554280422, COSV50753646; called by muse, mutect2
- PPP2R1A | c.650A>G p.Q217R | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as COSV100436120; called by muse, mutect2, varscan2
- PPP2R1A | c.1376G>A p.R459H | Missense Mutation (SNP) | VAF 29/50 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV59049488; called by muse, mutect2, varscan2
- RFLNB | c.432C>A p.C144* | Nonsense Mutation (SNP) | VAF 9/52 reads (17%) | catalogued as COSV100225029; called by muse, mutect2, varscan2
- RXFP3 | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV57505325; called by muse, mutect2, varscan2
- SIRPD | c.214C>T p.R72W | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.054); catalogued as rs552135708, COSV67546697; called by muse, mutect2, varscan2
- SLC27A6 | c.609G>C p.E203D | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.02); catalogued as COSV99322390; called by muse, mutect2, varscan2
- SMG1 | c.9937C>T p.R3313* | Nonsense Mutation (SNP) | VAF 11/57 reads (19%) | catalogued as COSV101245447; called by muse, mutect2, varscan2
- SORCS3 | c.2310C>G p.F770L | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100863457, COSV63795244; called by muse, mutect2, varscan2
- SOS1 | c.1286T>C p.I429T | Missense Mutation (SNP) | VAF 147/173 reads (85%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs755862687, COSV101216704, COSV67674597; called by muse, mutect2, varscan2
- SPOP | c.134G>T p.R45L | Missense Mutation (SNP) | VAF 85/142 reads (60%) | SIFT tolerated (0.79); PolyPhen benign (0.023); catalogued as COSV100753643, COSV61656237; called by muse, mutect2, varscan2
- SPRY4 | c.230C>T p.T77M (on ENST00000434127 / NM_001127496.3; = p.T100M on NM_030964.4) | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as rs774674946, CM133830, COSV59986194; called by muse, mutect2, varscan2
- TAS2R38 | c.704G>C p.R235P | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.92); catalogued as rs144212167, COSV101516370, COSV71885866; called by muse, mutect2, varscan2
- XDH | c.1999A>G p.I667V | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.033); catalogued as COSV101052106; called by muse, mutect2, varscan2
- ZDHHC15 | c.994G>T p.A332S | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT tolerated (0.68); PolyPhen benign (0.014); catalogued as rs1473421251, COSV100973701; called by muse, mutect2, varscan2
- ZMYM3 | c.878G>A p.R293H | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV100077579; called by muse, mutect2, varscan2
- ZNF831 | c.3557G>A p.C1186Y | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100925885; called by muse, mutect2, varscan2
- ZRANB3 | c.2205G>C p.M735I | Missense Mutation (SNP) | VAF 4/67 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.164); catalogued as COSV99922998; called by muse, mutect2
- TLE1 | c.1982_1984del p.F661del | In Frame Del (DEL) | VAF 16/22 reads (73%) | called by pindel, varscan2
- CDKL3 | c.786A>C p.I262= | Silent (SNP) | VAF 23/64 reads (36%) | catalogued as rs890028796, COSV99527702; called by muse, mutect2, varscan2
- FLT4 | c.1755C>T p.Y585= | Silent (SNP) | VAF 24/60 reads (40%) | catalogued as rs1415338572, COSV99986296; called by muse, mutect2, varscan2
- GPR55 | c.273G>A p.P91= | Silent (SNP) | VAF 12/27 reads (44%) | catalogued as rs370767476; called by muse, mutect2, varscan2
- GPX7 | c.222G>A p.L74= | Silent (SNP) | VAF 31/60 reads (52%) | catalogued as COSV100790903; called by muse, mutect2, varscan2
- IGSF1 | c.900C>T p.D300= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as rs376545217, COSV63835989; called by muse, mutect2, varscan2
- NR2C1 | c.1702T>C p.L568= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as rs1012595366, COSV100280295; called by muse, mutect2, varscan2
- NUP214 | c.4146G>A p.K1382= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as COSV100845187; called by muse, mutect2, varscan2
- PCDHB11 | c.2079G>A p.A693= | Silent (SNP) | VAF 20/211 reads (9%) | catalogued as rs373740953, COSV61310974; called by muse, mutect2
- PDE6C | c.1734G>T p.L578= | Silent (SNP) | VAF 59/118 reads (50%) | catalogued as COSV101008618; called by muse, mutect2, varscan2
- RHOV | c.456C>T p.N152= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV99592057; called by muse, mutect2, varscan2
- TBC1D5 | c.2262C>A p.S754= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as COSV99509661; called by muse, mutect2, varscan2
- TEAD4 | c.114C>T p.D38= | Silent (SNP) | VAF 33/69 reads (48%) | catalogued as rs370797807; called by muse, mutect2, varscan2
- TPM4 | c.*378G>A | 3'UTR (SNP) | VAF 6/136 reads (4%) | catalogued as COSV99959313; called by muse, mutect2
